Somatic mutation profile of tumor specimen TARGET-10-PARMYP-09A (aliquot TARGET-10-PARMYP-09A-01D) from TARGET case TARGET-10-PARMYP, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,076 days).
Specimen TARGET-10-PARMYP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f610e5b-9d1b-4fbc-8ba5-1b283c7f3c18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARMYP-10A (Blood Derived Normal), aliquot TARGET-10-PARMYP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/624fac26-bc2a-4412-8ae7-9d347993619b

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Intron 2, Frame Shift Ins 1, Nonsense Mutation 1, Frame Shift Del 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL8 | c.302C>T p.T101M | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs200147694, COSV64862846; called by muse, mutect2, varscan2
- ADAMTS19 | c.929G>C p.R310T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.258); catalogued as COSV99179619; called by muse, mutect2, varscan2
- ANO4 | c.584G>A p.R195H (on ENST00000392977 / NM_001286615.2; = p.R160H on NM_178826.4) | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.885); catalogued as rs778988665, COSV100152109; called by muse, mutect2
- ARHGAP22 | c.977C>T p.T326I | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.689); catalogued as rs753136487, COSV99985313; called by muse, mutect2, varscan2
- GABPA | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as rs948659417; called by muse, mutect2, varscan2
- LMLN | c.1546G>A p.A516T | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs762068015, COSV100218948; called by muse, mutect2, varscan2
- MBD5 | c.3020A>G p.N1007S | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs767692391; called by muse, mutect2, varscan2
- MRGPRX3 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs201547024; called by muse, mutect2, varscan2
- MYO15A | c.4534G>A p.V1512M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs371958829; called by muse, mutect2, varscan2
- PLPPR4 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs776709541, COSV64570894; called by muse, varscan2
- SORBS2 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1206275528, COSV53004542; called by muse, mutect2, varscan2
- UGT2B17 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 38/116 reads (33%) | catalogued as rs558443905, COSV100497173; called by muse, mutect2, varscan2
- COPS2 | c.889_890del p.Q297Gfs*8 | Frame Shift Del (DEL) | VAF 14/34 reads (41%) | called by pindel, varscan2
- ERICH6 | c.1211_1212insAGTAG p.S404Rfs*14 | Frame Shift Ins (INS) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- SREK1 | c.386T>C p.M129T | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- STPG2 | c.1126A>T p.S376C | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- BOC | c.1341G>A p.A447= | Silent (SNP) | VAF 41/123 reads (33%) | catalogued as rs766552892, COSV56354222; called by muse, mutect2, varscan2
- BTBD1 | c.549A>G p.L183= | Silent (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- CYP21A2 | c.438G>A p.E146= | Silent (SNP) | VAF 12/26 reads (46%) | called by muse, varscan2
- TTLL1 | c.846C>T p.F282= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs768299826, COSV99840272; called by muse, mutect2, varscan2
- CALD1 | c.2199+111T>A | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- IGLV4-69 | chr22:22031473 del C | 3'Flank (DEL) | VAF 9/72 reads (13%) | called by pindel*, varscan2
- RARRES2P7 | n.255G>A | RNA (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
- ZNF721 | c.-3+24944C>G | Intron (SNP) | VAF 35/91 reads (38%) | called by muse, mutect2, varscan2
